Somatic mutation profile of tumor specimen C3N-03000-02 (aliquot CPT0226490006) from CPTAC case C3N-03000, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 57.1 years (20,844 days).
Specimen C3N-03000-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a830dd08-d002-4d0e-a18d-0ad88cff461a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03000-31 (Blood Derived Normal), aliquot CPT0226510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a7bf050-6146-493d-83ec-2694c451d192

The open-access MAF lists 52 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, 3'UTR 2, 5'Flank 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 78/283 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 104/527 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APLP1 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 27/430 reads (6%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.997); catalogued as rs781528434, COSV55701542; called by muse, mutect2
- CMKLR1 | c.268G>A p.V90I (on ENST00000312143 / NM_001142344.2; = p.V88I on NM_004072.3) | Missense Mutation (SNP) | VAF 14/423 reads (3%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as rs1303270427, COSV100379420; called by muse, mutect2
- CNGB1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs369817749; called by muse, mutect2
- DHX16 | c.1645C>G p.L549V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV64564172; called by mutect2, varscan2
- DIDO1 | c.6641G>A p.R2214Q | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as rs369703114; called by muse, mutect2
- GAL3ST3 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 33/389 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150888474, COSV61748859; called by muse, mutect2
- IFIT2 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs768227773, COSV51079533; called by muse, mutect2
- IPCEF1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV99500639; called by muse, mutect2
- LHFPL5 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 71/445 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs566829909, COSV104420417; called by muse, mutect2, varscan2
- LRP1B | c.7289G>T p.R2430L | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67206126, COSV67212753; called by muse, mutect2, varscan2
- MLC1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs533294413; called by muse, mutect2
- MYH4 | c.5738G>A p.R1913Q | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151125083; called by muse, mutect2
- NELL2 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.752); catalogued as rs750566671, COSV61570866; called by muse, mutect2
- OTUD6A | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV57972732, COSV57973745; called by muse, mutect2
- PCDHA7 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 74/850 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV65346741; called by muse, mutect2
- PCDHAC1 | c.2198C>G p.S733* | Nonsense Mutation (SNP) | VAF 23/168 reads (14%) | catalogued as COSV99165243; called by muse, mutect2, varscan2
- RB1CC1 | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1323361735; called by muse, mutect2
- RIMBP2 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769276085, COSV55478173; called by muse, mutect2, varscan2
- RTN2 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1452457185; ClinVar: likely benign; called by muse, mutect2
- SHANK1 | c.6266C>T p.P2089L | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1260348115; called by muse, mutect2
- STOX1 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779394146, COSV53815324; called by muse, mutect2
- TRAF4 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs757460687, COSV99286374; called by muse, mutect2, varscan2
- ACAD11 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKS1A | c.1746A>T p.E582D | Missense Mutation (SNP) | VAF 48/522 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- CDKN2A | c.102_142del p.G35Dfs*71 | Frame Shift Del (DEL) | VAF 84/316 reads (27%) | called by mutect2, pindel
- FAM180B | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- GFOD1 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PDCD11 | c.5179G>A p.V1727M | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDGFRL | c.1097C>A p.T366N | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RASGRF1 | c.1982C>T p.T661M | Missense Mutation (SNP) | VAF 15/486 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- VCPIP1 | c.3454A>T p.S1152C | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- EFHD2 | c.102G>A p.A34= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1238413956; called by muse, varscan2
- EGF | c.1371A>G p.V457= | Silent (SNP) | VAF 50/328 reads (15%) | called by muse, mutect2, varscan2
- HCN1 | c.1689A>T p.S563= | Silent (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- IGHM | c.1350C>T p.T450= | Silent (SNP) | VAF 56/672 reads (8%) | catalogued as rs756477133; called by muse, mutect2
- MS4A14 | c.1446C>A p.S482= | Silent (SNP) | VAF 15/252 reads (6%) | called by muse, mutect2
- OBSCN | c.18801C>T p.T6267= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs753136423, COSV52782753; called by muse, mutect2, varscan2
- PCDHA13 | c.1683C>T p.N561= | Silent (SNP) | VAF 60/571 reads (11%) | catalogued as rs782324778, COSV56486193; called by muse, mutect2, varscan2
- PCDHGA2 | c.1722C>T p.G574= | Silent (SNP) | VAF 34/530 reads (6%) | catalogued as COSV53912616; called by muse, mutect2
- PELI3 | c.735C>T p.G245= | Silent (SNP) | VAF 31/388 reads (8%) | catalogued as rs773772009; called by muse, mutect2
- PXDNL | c.3264G>A p.P1088= | Silent (SNP) | VAF 15/320 reads (5%) | catalogued as COSV62486212; called by muse, mutect2
- SHC3 | c.738G>A p.A246= | Silent (SNP) | VAF 36/200 reads (18%) | catalogued as rs1371077393; called by muse, mutect2, varscan2
- TPO | c.2406C>T p.D802= | Silent (SNP) | VAF 14/508 reads (3%) | catalogued as rs779508239, COSV61094587, COSV61102965; called by muse, mutect2
- UPF1 | c.858C>T p.D286= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as rs1477145104, COSV53194445; called by muse, mutect2, varscan2
- ADAMTS17 | c.-46C>A | 5'UTR (SNP) | VAF 18/327 reads (6%) | called by muse, mutect2
- C4orf50 | chr4:5989703 G>A | 5'Flank (SNP) | VAF 15/129 reads (12%) | catalogued as rs892390528; called by muse, mutect2, varscan2
- CLN5 | c.*494G>A | 3'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- DCHS2 | n.8562C>T | RNA (SNP) | VAF 20/103 reads (19%) | catalogued as rs759791153, COSV61767417; called by muse, mutect2, varscan2
- IL2RG | c.455-47A>G | Intron (SNP) | VAF 61/188 reads (32%) | called by muse, mutect2, varscan2
- ZNF44 | c.*160G>C | 3'UTR (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
